TCGA case TCGA-XU-A92Y — Thymoma (TCGA-THYM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Thymic Epithelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: University Health Network. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fd15ff57-f121-40ea-a3b9-b66cbf34c1e0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 71 years; Vital status: Dead; Days to death: 3,488 days (9.5 years).

Diagnoses (2)
1. Thymoma, type B3, malignant (the primary disease): ICD-O-3 morphology code: 8585/3; ICD-10 code: C38.1; Tissue or organ of origin: Anterior mediastinum; Site of resection or biopsy: Anterior mediastinum; Classification of tumor: primary; Age at diagnosis: 71.2 years (26,021 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; Masaoka stage: Stage IIb; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 54 days; Days to treatment end: 79 days; Treatment dose: 40 Gy; Treatment outcome: Progressive Disease; Number of fractions: 20; Treatment anatomic sites: Regional Site.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS.
2. Recurrence of diagnosis 1 (Thymoma, type B3, malignant), site: Mediastinum, NOS. Age at diagnosis: 74.6 years (27,245 days); Days to diagnosis: 1,224 days (3.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 1,224 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Mediastinum, NOS; Days to recurrence: 1,224 days (3.4 years).
- Days to follow up: 3,488 days (9.5 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 67 kg; Height: 158 cm; BMI: 26.8.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XU-A92Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 60 mg.
  Slide TCGA-XU-A92Y-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-XU-A92Y-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XU-A92Y-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Stage record: Masaoka stage: IIb.
- Primary pathology, Histological type list: Histologic diagnosis: Thymoma, Type B3.
- Primary pathology: Method initial path diagnosis: Median Sternectomy; History myasthenia gravis: No.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 3,488 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 3,488 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,224 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XU-A92Y-01A-11D-A422-01): tumor purity 0.2, ploidy 2.2, whole-genome doublings 0.
